Somatic mutation profile of tumor specimen ALCH-B1HE-TTP1-A (aliquot ALCH-B1HE-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-B1HE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 65.8 years (24,036 days).
Specimen ALCH-B1HE-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc2fa347-f8cf-47f5-8796-14a41664ead2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1HE-NB1-A (Blood Derived Normal), aliquot ALCH-B1HE-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33029513-c4ad-45f7-94d8-c54a21b72485

The open-access MAF lists 517 somatic variants for this specimen: 349 protein-altering or splice-affecting, 88 silent, 80 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 297, Silent 88, Intron 24, Nonsense Mutation 19, RNA 19, Frame Shift Del 14, 5'Flank 11, 3'UTR 10, 5'UTR 10, Frame Shift Ins 8, Splice Site 6, 3'Flank 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRYBA1 | c.215+1G>A p.X72_splice | Splice Site (SNP) | VAF 111/315 reads (35%) | catalogued as rs1264025914, CS004398, CS116323, CS983334, COSV56601116; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KEAP1 | c.1409G>A p.R470H | Missense Mutation (SNP) | VAF 39/89 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen probably damaging (0.956); catalogued as COSV50285556; called by muse, mutect2, varscan2
- TP53 | c.783-2A>T p.X261_splice | Splice Site (SNP) | VAF 35/150 reads (23%) | hotspot (GDC flag); catalogued as COSV52818160, COSV52984227, COSV53085853; called by muse, mutect2, varscan2
- AC011005.1 | c.104T>C p.V35A | Missense Mutation (SNP) | VAF 114/361 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0.018); catalogued as rs778455177; called by muse, mutect2, varscan2
- ACSM1 | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104374966; called by muse, mutect2, varscan2
- ADAM29 | c.2128G>A p.V710I | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.482); catalogued as rs1467291923, COSV63665964; called by muse, mutect2, varscan2
- ADAMTS5 | c.1715C>A p.S572Y | Missense Mutation (SNP) | VAF 49/81 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV53185936; called by muse, mutect2, varscan2
- ADAMTS6 | c.860G>T p.R287L | Missense Mutation (SNP) | VAF 73/251 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as rs1295702367, COSV66858016; called by muse, mutect2, varscan2
- AGBL4 | c.634G>T p.D212Y | Missense Mutation (SNP) | VAF 132/240 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); catalogued as COSV100886802; called by muse, mutect2, varscan2
- ALOX5 | c.1517T>C p.L506P | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs763034929; called by muse, mutect2, varscan2
- APCDD1L | c.686C>A p.A229E | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.267); catalogued as rs1172718690; called by muse, mutect2, varscan2
- ATRX | c.7094C>T p.S2365L | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV64871264, COSV64886442; called by muse, mutect2, varscan2
- BEND6 | c.548G>T p.R183L | Missense Mutation (SNP) | VAF 128/200 reads (64%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV100876926; called by muse, mutect2, varscan2
- BNC1 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 70/148 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100597116, COSV61757588; called by muse, mutect2, varscan2
- C6 | c.1106G>T p.G369V | Missense Mutation (SNP) | VAF 104/263 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54706235; called by muse, mutect2, varscan2
- CACNB1 | c.580C>A p.L194M | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV59999691; called by muse, mutect2, varscan2
- CMYA5 | c.1291C>A p.H431N | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV101484169; called by muse, mutect2, varscan2
- CNR1 | c.577C>G p.L193V | Missense Mutation (SNP) | VAF 63/139 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV62990871; called by muse, mutect2, varscan2
- COL5A3 | c.1930G>T p.G644* | Nonsense Mutation (SNP) | VAF 7/12 reads (58%) | catalogued as COSV53419415; called by muse, mutect2, varscan2
- COL8A1 | c.1357G>A p.G453S | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99658394; called by muse, mutect2
- COL9A1 | c.322C>A p.P108T | Missense Mutation (SNP) | VAF 167/277 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1381300078; called by muse, mutect2, varscan2
- CUBN | c.5317G>T p.G1773C | Missense Mutation (SNP) | VAF 32/220 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1564440503, COSV64713460; called by muse, mutect2, varscan2
- DLGAP2 | c.1063G>T p.E355* | Nonsense Mutation (SNP) | VAF 43/92 reads (47%) | catalogued as COSV70096775; called by muse, mutect2, varscan2
- DNAH5 | c.12281G>T p.G4094V | Missense Mutation (SNP) | VAF 168/594 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54214619; called by muse, mutect2, varscan2
- DOP1A | c.5273G>C p.R1758P | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99382273; called by muse, mutect2, varscan2
- DPYS | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 91/298 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60910645; called by muse, mutect2, varscan2
- DRICH1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.801); catalogued as rs1176314800, COSV58503903; called by muse, mutect2, varscan2
- DTHD1 | c.339G>T p.E113D (on ENST00000456874; = p.E238D on NM_001170700.3) | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV62630480; called by muse, varscan2
- EPS15 | c.2441G>A p.S814N | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.361); catalogued as rs373517965; called by muse, mutect2, varscan2
- ESRRG | c.1162G>A p.V388I | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as rs141423098; called by muse, mutect2, varscan2
- FAM20C | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 36/301 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1451598113; called by muse, mutect2, varscan2
- FBN3 | c.698G>T p.R233L | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs776301980; called by muse, mutect2, varscan2
- FLNC | c.6031G>T p.G2011W | Missense Mutation (SNP) | VAF 91/305 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554400962; called by muse, mutect2, varscan2
- FOXA2 | c.1316C>T p.A439V (on ENST00000377115 / NM_153675.3; = p.A445V on NM_021784.5) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs758059957, COSV101008583; called by muse, mutect2, varscan2
- FOXL2NB | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.047); catalogued as rs1369574093; called by muse, mutect2, varscan2
- GABRB3 | c.785G>T p.W262L | Missense Mutation (SNP) | VAF 43/239 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54655293; called by muse, mutect2, varscan2
- GABRD | c.817C>T p.Q273* | Nonsense Mutation (SNP) | VAF 53/90 reads (59%) | catalogued as rs1405824159, COSV101059578; called by muse, mutect2, varscan2
- GARNL3 | c.2915A>G p.N972S | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); catalogued as rs1297544485; called by muse, mutect2, varscan2
- GLP2R | c.802C>G p.H268D | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.771); catalogued as COSV52324389, COSV52327487; called by muse, mutect2, varscan2
- GNB1L | c.105G>T p.Q35H | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.035); catalogued as rs1230894900; called by muse, mutect2, varscan2
- GPR179 | c.4555G>A p.G1519R (on ENST00000621958; = p.G1518R on NM_001004334.4) | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.085); catalogued as rs769524780; called by muse, mutect2, varscan2
- GRXCR1 | c.851G>T p.R284L | Missense Mutation (SNP) | VAF 92/316 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.28); catalogued as rs769123480, COSV67672312, COSV99063713; called by muse, mutect2, varscan2
- GTF3C1 | c.557G>T p.R186L | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62238693, COSV62245796; called by muse, mutect2, varscan2
- H3C8 | c.271A>G p.M91V | Missense Mutation (SNP) | VAF 203/373 reads (54%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.011); catalogued as rs764941245; called by muse, mutect2, varscan2
- HDAC8 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as CM144944; called by muse, mutect2, varscan2
- HEPACAM | c.449T>C p.V150A | Missense Mutation (SNP) | VAF 39/198 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as rs993273312; called by muse, mutect2, varscan2
- HS3ST3A1 | c.1194del p.H400Tfs*12 | Frame Shift Del (DEL) | VAF 14/64 reads (22%) | catalogued as COSV99404579; called by mutect2, pindel, varscan2
- HTR1A | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 42/266 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202063419, COSV100109259; called by muse, mutect2, varscan2
- IGKV1D-16 | c.170G>A p.W57* | Nonsense Mutation (SNP) | VAF 178/481 reads (37%) | catalogued as rs1374686714; called by muse, mutect2, varscan2
- INSC | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746823149; called by muse, mutect2, varscan2
- KCNQ2 | c.1846G>T p.D616Y (on ENST00000359125 / NM_172107.4; = p.D588Y on NM_004518.6) | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60546575; called by muse, mutect2, varscan2
- KDM5A | c.2786G>C p.G929A | Missense Mutation (SNP) | VAF 76/240 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV66996556; called by muse, mutect2, varscan2
- KHDRBS2 | c.764G>T p.G255V | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.911); catalogued as COSV55447739; called by muse, mutect2, varscan2
- KPRP | c.893C>G p.P298R | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100908731, COSV64221842; called by muse, mutect2
- KRTAP10-9 | c.79T>A p.C27S | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59969479; called by muse, mutect2, varscan2
- LAMA2 | c.4751del p.G1584Vfs*11 | Frame Shift Del (DEL) | VAF 102/281 reads (36%) | catalogued as CM030232; called by mutect2, pindel, varscan2
- MAVS | c.1247C>T p.S416L | Missense Mutation (SNP) | VAF 22/274 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs773000355, COSV100816272; called by muse, mutect2
- MEFV | c.2102C>T p.A701V | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.087); catalogued as rs760439284, COSV54824587; called by muse, mutect2, varscan2
- MET | c.2103-2A>T p.X701_splice | Splice Site (SNP) | VAF 91/347 reads (26%) | catalogued as rs1470403316, COSV59263298; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYH2 | c.3522G>T p.E1174D | Missense Mutation (SNP) | VAF 83/359 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV55432355; called by muse, mutect2, varscan2
- MYOG | c.22C>G p.P8A | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.527); catalogued as rs200192512, COSV99613950; called by muse, mutect2, varscan2
- OR2AG2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1182794096; called by muse, mutect2, varscan2
- OR4A47 | c.170T>C p.M57T | Missense Mutation (SNP) | VAF 52/231 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.529); catalogued as rs367727363; called by muse, mutect2, varscan2
- OR5AN1 | c.391C>A p.L131M | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58323205; called by muse, mutect2, varscan2
- OR5H2 | c.495A>C p.E165D | Missense Mutation (SNP) | VAF 68/328 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV62350482; called by muse, mutect2, varscan2
- OSBPL7 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as rs767122644, COSV99136763; called by muse, mutect2, varscan2
- PCDHA13 | c.1856G>T p.R619L | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.644); catalogued as COSV56549312; called by muse, mutect2, varscan2
- PCDHGA10 | c.2279A>G p.E760G | Missense Mutation (SNP) | VAF 77/392 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.179); catalogued as rs899212436; called by muse, mutect2, varscan2
- PCDHGA2 | c.653del p.G218Vfs*13 | Frame Shift Del (DEL) | VAF 50/169 reads (30%) | catalogued as COSV54036069; called by mutect2, pindel, varscan2
- PCDHGB7 | c.1444G>T p.G482W | Missense Mutation (SNP) | VAF 53/176 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53927206; called by muse, mutect2, varscan2
- PCDHGC3 | c.1745G>T p.R582L | Missense Mutation (SNP) | VAF 134/351 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV52767648; called by muse, mutect2, varscan2
- PDZRN3 | c.2092G>T p.E698* | Nonsense Mutation (SNP) | VAF 92/168 reads (55%) | catalogued as COSV55193664; called by muse, varscan2
- PLCB3 | c.1016G>T p.G339V | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54185958; called by muse, mutect2, varscan2
- PLD3 | c.431G>T p.G144V | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761353429; called by muse, mutect2, varscan2
- POTED | c.1524G>A p.M508I | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs756972591; called by muse, mutect2, varscan2
- PRDM2 | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 75/149 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99342728; called by muse, mutect2, varscan2
- PRRC2A | c.6439G>A p.G2147R | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs933149390; called by muse, mutect2, varscan2
- PYHIN1 | c.424C>A p.P142T | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as rs780075398, COSV100932343, COSV63722905; called by muse, mutect2, varscan2
- RIC8A | c.880G>C p.E294Q | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.409); catalogued as COSV100254726; called by muse, mutect2, varscan2
- RYR2 | c.9679C>T p.R3227C | Missense Mutation (SNP) | VAF 146/197 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs747271394, COSV63695082; called by muse, mutect2, varscan2
- RYR3 | c.300C>A p.H100Q | Missense Mutation (SNP) | VAF 48/274 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66796070; called by muse, mutect2, varscan2
- SALL1 | c.405C>A p.S135R | Missense Mutation (SNP) | VAF 95/459 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.024); catalogued as COSV51765337, COSV99171628; called by muse, mutect2, varscan2
- SCLY | c.949G>A p.A317T (on ENST00000651534; = p.A309T on NM_016510.7) | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as rs777079762; called by muse, mutect2, varscan2
- SDHA | c.1567G>T p.A523S | Missense Mutation (SNP) | VAF 152/481 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as rs1554001820; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEPTIN12 | c.970G>T p.G324W | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51618362; called by muse, mutect2, varscan2
- SMAD6 | c.1405G>T p.A469S | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1416212959; called by muse, mutect2, varscan2
- SMC4 | c.395A>G p.Y132C | Missense Mutation (SNP) | VAF 149/671 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as rs922296681, COSV58449455; called by muse, mutect2, varscan2
- SMPDL3A | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs747741568; called by muse, mutect2, varscan2
- SNTG1 | c.108G>T p.L36F | Missense Mutation (SNP) | VAF 89/271 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52428719; called by muse, mutect2, varscan2
- SPATC1L | c.784G>C p.E262Q (on ENST00000291672 / NM_001142854.2; = p.E108Q on NM_032261.5) | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.964); catalogued as rs760305218, COSV52432513; called by muse, mutect2, varscan2
- TAS2R60 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 103/316 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.399); catalogued as rs1271719370; called by muse, mutect2, varscan2
- TCHP | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.281); catalogued as rs1050875883; called by muse, mutect2, varscan2
- TDG | c.37C>G p.Q13E | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.073); catalogued as COSV99904172; called by muse, mutect2
- TMEM132E | c.1825C>G p.R609G (on ENST00000321639; = p.R699G on NM_001304438.2) | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as COSV100396333; called by muse, mutect2, varscan2
- TRIM60 | c.509T>C p.V170A | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.065); catalogued as rs775706864; called by muse, mutect2, varscan2
- TYR | c.833G>T p.R278L | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.49); catalogued as COSV54475107, COSV99633723, COSV99633969; called by muse, mutect2, varscan2
- UNKL | c.1019G>A p.G340E | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.224); catalogued as rs939975601; called by muse, mutect2, varscan2
- UQCRHL | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs750545008; called by muse, mutect2, varscan2
- USF2 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 11/169 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.07); catalogued as rs1361550595; called by muse, mutect2
- VAV1 | c.941G>T p.R314I | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV58390181; called by mutect2, varscan2
- VWDE | c.598G>C p.E200Q | Missense Mutation (SNP) | VAF 82/237 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV51722408; called by muse, mutect2, varscan2
- XKR4 | c.19G>C p.G7R | Missense Mutation (SNP) | VAF 93/358 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV100533940; called by muse, mutect2, varscan2
- ZNF365 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 34/244 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776084132; called by muse, mutect2, varscan2
- ZNF467 | c.979C>G p.P327A | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs1392323166; called by muse, mutect2, varscan2
- ZNF479 | c.1145C>T p.T382I | Missense Mutation (SNP) | VAF 69/196 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs539820985; called by muse, mutect2, varscan2
- ZNF519 | c.1130G>T p.R377I | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV73913682; called by muse, mutect2, varscan2
- ABCA9 | c.1739T>A p.L580H | Missense Mutation (SNP) | VAF 138/349 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACACB | c.5011A>T p.R1671* | Nonsense Mutation (SNP) | VAF 44/62 reads (71%) | called by muse, mutect2, varscan2
- ACSBG2 | c.704G>T p.G235V | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ADAMTSL3 | c.4689G>T p.R1563S | Missense Mutation (SNP) | VAF 48/205 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- AEBP1 | c.104dup p.E36Gfs*13 | Frame Shift Ins (INS) | VAF 96/275 reads (35%) | called by mutect2, pindel, varscan2
- AGBL1 | c.3154C>G p.Q1052E | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ALDH1L1 | c.578A>T p.Q193L | Missense Mutation (SNP) | VAF 54/205 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALOXE3 | c.150A>C p.V50= | Splice Region (SNP) | VAF 20/104 reads (19%) | called by muse, mutect2, varscan2
- ANKRD42 | c.390A>T p.R130S | Missense Mutation (SNP) | VAF 80/253 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.013); called by muse, varscan2
- APBA1 | c.592T>A p.Y198N | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- AQR | c.2146G>A p.D716N | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARMC5 | c.489G>C p.Q163H | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- ARPP21 | c.1244G>T p.S415I | Missense Mutation (SNP) | VAF 51/94 reads (54%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- ATP10B | c.863A>C p.Y288S | Missense Mutation (SNP) | VAF 59/160 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AZIN2 | c.130G>T p.A44S | Missense Mutation (SNP) | VAF 85/166 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- BAG6 | c.973C>T p.R325* | Nonsense Mutation (SNP) | VAF 20/154 reads (13%) | called by muse, mutect2, varscan2
- BDP1 | c.1851A>T p.Q617H | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- BMP4 | c.147G>T p.Q49H | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2
- BRWD1 | c.1541A>G p.Q514R | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by mutect2, varscan2
- C12orf42 | c.556G>T p.E186* | Nonsense Mutation (SNP) | VAF 62/112 reads (55%) | called by muse, mutect2, varscan2
- C2orf73 | c.685C>A p.Q229K | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- CACNA1B | c.6956G>T p.G2319V | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CALCB | c.23C>A p.P8H | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- CAMK1D | c.604G>T p.V202F | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC110 | c.811A>T p.T271S | Missense Mutation (SNP) | VAF 10/266 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.115); called by muse, mutect2
- CCDC141 | c.1997T>C p.L666P | Missense Mutation (SNP) | VAF 93/265 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CD163 | c.2927T>C p.L976S | Missense Mutation (SNP) | VAF 84/247 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- CDK8 | c.437G>T p.W146L | Missense Mutation (SNP) | VAF 248/400 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- CDS1 | c.995dup p.Y332* | Nonsense Mutation (INS) | VAF 19/135 reads (14%) | called by mutect2, pindel, varscan2
- CEP89 | c.1346G>C p.R449T | Missense Mutation (SNP) | VAF 87/271 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CERKL | c.59A>T p.E20V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CFAP299 | c.136G>T p.V46L | Missense Mutation (SNP) | VAF 53/168 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- CHD2 | c.4712A>T p.D1571V | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.425); called by muse, mutect2
- CHKA | c.590A>G p.Y197C | Missense Mutation (SNP) | VAF 109/298 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CHODL | c.70G>A p.V24M | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- CHRNA4 | c.1070T>A p.L357H | Missense Mutation (SNP) | VAF 95/265 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- CLCN7 | c.1171G>T p.V391L | Missense Mutation (SNP) | VAF 126/397 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CMA1 | c.174del p.N59Tfs*4 | Frame Shift Del (DEL) | VAF 123/321 reads (38%) | called by mutect2, pindel, varscan2
- COL22A1 | c.4076C>A p.P1359H | Missense Mutation (SNP) | VAF 101/293 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL22A1 | c.3236G>T p.R1079L | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- COL4A4 | c.650G>A p.G217E | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CS | c.80G>T p.S27I | Missense Mutation (SNP) | VAF 79/129 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- CSMD3 | c.1055C>A p.T352N | Missense Mutation (SNP) | VAF 112/410 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CSTL1 | c.19A>G p.R7G | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2
- CTDNEP1 | c.167T>C p.L56P | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, varscan2
- CYFIP2 | c.3317C>A p.T1106N (on ENST00000616178 / NM_001291722.2; = p.T1081N on NM_014376.4) | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, varscan2
- CYP4B1 | c.647G>T p.S216I | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- DAPK1 | c.611G>T p.G204V | Missense Mutation (SNP) | VAF 84/128 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCAF8L1 | c.790C>A p.Q264K | Missense Mutation (SNP) | VAF 62/109 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- DDX1 | c.817G>A p.G273S | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- DDX52 | c.1109A>T p.N370I | Missense Mutation (SNP) | VAF 51/169 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- DERA | c.245A>G p.D82G | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DNAH6 | c.5390C>T p.T1797I | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- DNER | c.353del p.G118Afs*56 | Frame Shift Del (DEL) | VAF 24/68 reads (35%) | called by pindel, varscan2
- DOCK10 | c.5633A>G p.Y1878C | Missense Mutation (SNP) | VAF 71/251 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- DOCK2 | c.4213+1G>T p.X1405_splice | Splice Site (SNP) | VAF 8/37 reads (22%) | called by muse, mutect2, varscan2
- DPH6 | c.72del p.H25Ifs*6 | Frame Shift Del (DEL) | VAF 20/123 reads (16%) | called by mutect2, pindel, varscan2
- DPP4 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 51/207 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- DRICH1 | c.409G>T p.G137C | Missense Mutation (SNP) | VAF 62/241 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DROSHA | c.38A>G p.H13R | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- DST | c.16750T>A p.L5584M (on ENST00000361203 / NM_001374722.1; = p.L3281M on NM_015548.5) | Missense Mutation (SNP) | VAF 88/130 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- EAF1 | c.388C>A p.P130T | Missense Mutation (SNP) | VAF 91/184 reads (49%) | SIFT tolerated (0.72); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ECEL1 | c.1864+1G>T p.X622_splice | Splice Site (SNP) | VAF 20/84 reads (24%) | called by muse, mutect2, varscan2
- ECEL1 | c.1864G>T p.G622W | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EFCC1 | c.223C>A p.P75T | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- EGF | c.1862C>A p.P621Q | Missense Mutation (SNP) | VAF 77/273 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- ELAPOR2 | c.1400G>T p.G467V (on ENST00000450689 / NM_001142749.3; = p.G300V on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/159 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- EMCN | c.696G>T p.Q232H | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHA3 | c.1560C>A p.N520K | Missense Mutation (SNP) | VAF 46/79 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- FAHD2B | c.338T>G p.M113R | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- FAM193A | c.1141A>C p.S381R | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- FAM216B | c.367T>C p.S123P | Missense Mutation (SNP) | VAF 98/154 reads (64%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- FAT3 | c.8261dup p.I2755Hfs*12 | Frame Shift Ins (INS) | VAF 39/134 reads (29%) | called by mutect2, pindel, varscan2
- FGF20 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 47/123 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- FGF5 | c.5G>T p.S2I | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- FOXB2 | c.983C>A p.A328D | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- FOXK2 | c.866C>A p.T289N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- FSIP2 | c.11149A>G p.M3717V | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- GAL3ST3 | c.658G>T p.D220Y | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- GAL3ST4 | c.778A>T p.I260F | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GALNT2 | c.817+1dup | Frame Shift Ins (INS) | VAF 72/121 reads (60%) | called by mutect2, pindel, varscan2
- GCG | c.430C>A p.R144S | Missense Mutation (SNP) | VAF 134/414 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- GLDN | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 42/213 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- GNAO1 | c.834G>C p.K278N | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GOLGA6L2 | c.1599G>C p.M533I | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- GSE1 | c.961G>T p.E321* | Nonsense Mutation (SNP) | VAF 30/74 reads (41%) | called by muse, mutect2, varscan2
- GSS | c.146del p.P49Hfs*27 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | called by pindel, varscan2
- H2BC18 | c.22G>T p.A8S | Missense Mutation (SNP) | VAF 322/676 reads (48%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); called by mutect2, varscan2
- HAUS8 | c.619del p.E207Sfs*43 | Frame Shift Del (DEL) | VAF 22/144 reads (15%) | called by mutect2, pindel, varscan2
- HBG2 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 70/577 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- HERC6 | c.2394dup p.E799Rfs*16 | Frame Shift Ins (INS) | VAF 39/164 reads (24%) | called by mutect2, pindel, varscan2
- HHLA1 | c.17C>A p.S6* | Nonsense Mutation (SNP) | VAF 94/292 reads (32%) | called by muse, mutect2, varscan2
- HK3 | c.824G>T p.G275V | Missense Mutation (SNP) | VAF 63/161 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HLX | c.511A>G p.S171G | Missense Mutation (SNP) | VAF 248/325 reads (76%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- HOXA1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 164/509 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- HOXA7 | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- HTR5A | c.427A>G p.I143V | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- IFT140 | c.1963C>T p.Q655* | Nonsense Mutation (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- IGKV1D-42 | c.78G>T p.M26I | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- IL6 | c.389A>G p.Q130R | Missense Mutation (SNP) | VAF 95/255 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- INPP4B | c.49C>G p.P17A | Missense Mutation (SNP) | VAF 139/482 reads (29%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- IPO11 | c.1152G>C p.W384C | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGBL1 | c.1427G>C p.C476S | Missense Mutation (SNP) | VAF 168/267 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KATNIP | c.2778G>T p.E926D | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- KCNG4 | c.1101C>A p.C367* | Nonsense Mutation (SNP) | VAF 170/402 reads (42%) | called by muse, mutect2, varscan2
- KCNH8 | c.1670G>T p.R557L | Missense Mutation (SNP) | VAF 135/232 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- KCTD18 | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 71/194 reads (37%) | called by muse, mutect2, varscan2
- KLHDC9 | c.185A>C p.D62A | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KRT9 | c.1510G>T p.G504C | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LATS1 | c.1496A>T p.K499I | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LONRF2 | c.1072T>C p.S358P | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LOXL2 | c.273C>A p.H91Q | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.74); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- LPO | c.1203C>A p.N401K | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRK2 | c.58A>G p.I20V | Missense Mutation (SNP) | VAF 348/743 reads (47%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- LZTS3 | c.1628T>A p.M543K (on ENST00000329152; = p.M497K on NM_001282533.2) | Missense Mutation (SNP) | VAF 90/210 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- MAGEB6B | c.277A>T p.S93C | Missense Mutation (SNP) | VAF 77/122 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- MALRD1 | c.4912G>A p.A1638T | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- MARK1 | c.715G>T p.D239Y | Missense Mutation (SNP) | VAF 444/572 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MGAM | c.2761C>T p.P921S | Missense Mutation (SNP) | VAF 45/420 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, varscan2
- MGAM | c.5411T>A p.V1804E | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MGAM2 | c.1277G>C p.R426T | Missense Mutation (SNP) | VAF 90/262 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- MRGPRX4 | c.397C>A p.R133S | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- MTMR3 | c.2129C>T p.A710V | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MUC16 | c.4396A>G p.T1466A | Missense Mutation (SNP) | VAF 43/256 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- MUC19 | c.331C>T p.L111F | Missense Mutation (SNP) | VAF 115/268 reads (43%) | SIFT tolerated, low confidence (0.33); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- MUC7 | c.314T>A p.L105* | Nonsense Mutation (SNP) | VAF 43/179 reads (24%) | called by muse, mutect2, varscan2
- MYH10 | c.103C>A p.L35I | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- MYH13 | c.3174G>T p.K1058N | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- MYH2 | c.3523G>C p.A1175P | Missense Mutation (SNP) | VAF 85/356 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- MYO15A | c.1049A>T p.D350V | Missense Mutation (SNP) | VAF 166/344 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- MYO15A | c.2198C>T p.P733L | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, mutect2
- MYO15A | c.9901C>T p.P3301S | Missense Mutation (SNP) | VAF 22/293 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); called by muse, mutect2
- MYO5A | c.217G>C p.D73H | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAALAD2 | c.1341A>T p.E447D | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- NCAM1 | c.2332G>C p.A778P (on ENST00000316851 / NM_181351.5; = p.A768P on NM_000615.7) | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- NCOA6 | c.5899dup p.S1967Ffs*36 | Frame Shift Ins (INS) | VAF 24/92 reads (26%) | called by mutect2, varscan2
- NCOA6 | c.5897dup p.S1967Vfs*36 | Frame Shift Ins (INS) | VAF 20/111 reads (18%) | called by mutect2*, pindel, varscan2*
- NLRP10 | c.1843G>T p.E615* | Nonsense Mutation (SNP) | VAF 32/130 reads (25%) | called by muse, mutect2, varscan2
- NMBR | c.261del p.D89Tfs*30 | Frame Shift Del (DEL) | VAF 39/228 reads (17%) | called by mutect2, pindel, varscan2
- NMNAT2 | c.490T>C p.C164R | Missense Mutation (SNP) | VAF 182/250 reads (73%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NOS3 | c.820T>C p.C274R | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOTCH1 | c.5293G>T p.G1765C | Missense Mutation (SNP) | VAF 150/256 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- NOTCH3 | c.2295G>C p.Q765H | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- NRG3 | c.1547C>T p.S516L | Missense Mutation (SNP) | VAF 78/161 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- NRK | c.4102T>A p.S1368T | Missense Mutation (SNP) | VAF 104/160 reads (65%) | SIFT tolerated, low confidence (0.31); PolyPhen probably damaging (0.992); called by muse, varscan2
- OR10J1 | c.401T>C p.V134A | Missense Mutation (SNP) | VAF 126/237 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- OR10J5 | c.522C>A p.D174E | Missense Mutation (SNP) | VAF 28/285 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR10W1 | c.726G>T p.Q242H | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- OR14K1 | c.290T>C p.L97S | Missense Mutation (SNP) | VAF 99/407 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- OR2AG1 | c.725C>A p.S242Y | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- OR52N1 | c.930T>A p.F310L | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, varscan2
- OR8H1 | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 84/257 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- OR8I2 | c.506G>T p.C169F | Missense Mutation (SNP) | VAF 104/383 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR9A4 | c.407T>C p.M136T | Missense Mutation (SNP) | VAF 76/216 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.259); called by muse, varscan2
- OSBPL2 | c.1310G>T p.R437L (on ENST00000313733 / NM_144498.4; = p.R425L on NM_014835.4) | Missense Mutation (SNP) | VAF 63/178 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- PAM | c.1335A>C p.E445D | Missense Mutation (SNP) | VAF 90/357 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PAPPA2 | c.1945G>T p.V649L | Missense Mutation (SNP) | VAF 63/123 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- PARD6B | c.542T>C p.V181A | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- PARP15 | c.1099G>T p.G367C (on ENST00000464300 / NM_001113523.3; = p.G133C on NM_152615.2) | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHA3 | c.477T>G p.D159E | Missense Mutation (SNP) | VAF 146/414 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGA1 | c.828A>C p.E276D | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- PDCL3 | c.627G>T p.E209D | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); called by muse, mutect2
- PDIA6 | c.13C>G p.L5V | Missense Mutation (SNP) | VAF 30/131 reads (23%) | PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PDZRN3 | c.2021del p.G674Afs*15 | Frame Shift Del (DEL) | VAF 60/158 reads (38%) | called by pindel, varscan2
- PEF1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 79/183 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- PI4KA | c.4382G>T p.G1461V | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- PLD3 | c.430G>C p.G144R | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POM121L12 | c.35T>A p.L12H | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.263); called by muse, mutect2
- POTEH | c.387G>C p.K129N | Missense Mutation (SNP) | VAF 66/760 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, varscan2
- PPP1R13L | c.2446G>T p.G816W | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP4R3C | c.1895C>A p.S632* | Nonsense Mutation (SNP) | VAF 28/46 reads (61%) | called by muse, mutect2, varscan2
- PRDM16 | c.2685C>A p.H895Q | Missense Mutation (SNP) | VAF 54/97 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PRPF40A | c.2110G>A p.D704N | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- PTHLH | c.396A>T p.K132N | Missense Mutation (SNP) | VAF 61/248 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PTPRZ1 | c.4847C>G p.A1616G | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- RALGAPA1 | c.103A>T p.I35F | Missense Mutation (SNP) | VAF 53/281 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- RASA2 | c.1423C>T p.P475S | Missense Mutation (SNP) | VAF 70/232 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RASGRF1 | c.3458A>T p.K1153M | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- RBP3 | c.5dup p.M2Ifs*37 | Frame Shift Ins (INS) | VAF 50/172 reads (29%) | called by pindel, varscan2
- RBP3 | c.40T>G p.C14G | Missense Mutation (SNP) | VAF 91/234 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.143); called by muse, varscan2
- RDH14 | c.661A>T p.K221* | Nonsense Mutation (SNP) | VAF 67/281 reads (24%) | called by muse, mutect2, varscan2
- RECK | c.722A>C p.E241A | Missense Mutation (SNP) | VAF 127/203 reads (63%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- RECK | c.723G>T p.E241D | Missense Mutation (SNP) | VAF 130/208 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- RFPL4AL1 | c.67C>G p.Q23E | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.095); called by mutect2, varscan2
- RGPD3 | c.4082G>T p.R1361M | Missense Mutation (SNP) | VAF 76/648 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2
- RIPK4 | c.304G>T p.G102C | Missense Mutation (SNP) | VAF 98/170 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ROCK1 | c.3433G>C p.V1145L | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2
- RTL9 | c.2454G>T p.M818I | Missense Mutation (SNP) | VAF 106/159 reads (67%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SATB2 | c.875T>C p.I292T | Missense Mutation (SNP) | VAF 111/269 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SCAI | c.1172C>T p.T391I (on ENST00000336505 / NM_001144877.3; = p.T414I on NM_173690.5) | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SCN3A | c.4993G>T p.V1665F | Missense Mutation (SNP) | VAF 52/271 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SEMA3E | c.457-1G>T p.X153_splice | Splice Site (SNP) | VAF 113/385 reads (29%) | called by muse, mutect2, varscan2
- SETX | c.1724A>T p.Q575L | Missense Mutation (SNP) | VAF 70/238 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- SIM1 | c.1928_1929delinsA p.P643Hfs*16 | Frame Shift Del (DEL) | VAF 75/354 reads (21%) | called by pindel, varscan2*
- SLC26A7 | c.85A>T p.R29* | Nonsense Mutation (SNP) | VAF 54/193 reads (28%) | called by muse, mutect2, varscan2
- SLC44A5 | c.175G>T p.A59S | Missense Mutation (SNP) | VAF 65/120 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- SLC7A9 | c.1456C>G p.P486A | Missense Mutation (SNP) | VAF 146/402 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC8A1 | c.651G>T p.W217C | Missense Mutation (SNP) | VAF 43/237 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLITRK3 | c.2911G>C p.E971Q | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SLITRK4 | c.669del p.L224* | Frame Shift Del (DEL) | VAF 140/261 reads (54%) | called by mutect2, pindel, varscan2
- SOHLH1 | c.295C>A p.Q99K | Missense Mutation (SNP) | VAF 232/378 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SPATA31E1 | c.834C>A p.S278R | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- SPDL1 | c.1637G>T p.S546I | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- STARD9 | c.8621T>A p.V2874E | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- STARD9 | c.14020G>T p.G4674C | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SVIL | c.6035A>G p.D2012G (on ENST00000355867 / NM_021738.3; = p.D1586G on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/199 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TDRD12 | c.254C>A p.A85E | Missense Mutation (SNP) | VAF 66/138 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TENM2 | c.2870A>T p.Y957F (on ENST00000518659 / NM_001122679.2; = p.Y725F on NM_001080428.3) | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- TENM2 | c.4196G>T p.R1399L (on ENST00000518659 / NM_001122679.2; = p.R1160L on NM_001080428.3) | Missense Mutation (SNP) | VAF 113/272 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TFAP2D | c.983A>G p.Q328R | Missense Mutation (SNP) | VAF 125/205 reads (61%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- TH | c.751C>T p.P251S (on ENST00000381178 / NM_199292.3; = p.P220S on NM_000360.4) | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- TM9SF3 | c.1624A>C p.K542Q | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- TMEM176B | c.101C>G p.T34R | Missense Mutation (SNP) | VAF 122/335 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- TMPRSS15 | c.1115G>C p.S372T | Missense Mutation (SNP) | VAF 173/430 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TNPO3 | c.1828G>A p.V610M | Missense Mutation (SNP) | VAF 81/245 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- TOX3 | c.1604C>G p.P535R | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- TP53 | c.468_469del p.V157Pfs*23 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | called by pindel, varscan2
- TP63 | c.457A>T p.S153C | Missense Mutation (SNP) | VAF 129/505 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TRAV34 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT tolerated (0.22); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TRIM55 | c.1580G>A p.S527N | Missense Mutation (SNP) | VAF 105/348 reads (30%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIO | c.7439A>T p.Q2480L | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- TTC34 | c.1622A>G p.Q541R | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- TTC6 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- TTLL7 | c.58A>G p.T20A | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TTN | c.79958T>C p.L26653P (on ENST00000591111; = p.L19229P on NM_003319.4) | Missense Mutation (SNP) | VAF 58/251 reads (23%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTN | c.66091C>G p.Q22031E (on ENST00000591111; = p.Q14607E on NM_003319.4) | Missense Mutation (SNP) | VAF 12/71 reads (17%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- UGT1A1 | c.920dup p.L307Ffs*18 | Frame Shift Ins (INS) | VAF 51/187 reads (27%) | called by mutect2, pindel, varscan2
- UNC13A | c.4159G>A p.E1387K | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- USH2A | c.1705G>C p.A569P | Missense Mutation (SNP) | VAF 147/213 reads (69%) | SIFT tolerated (0.21); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- VAC14 | c.1211T>G p.L404R | Missense Mutation (SNP) | VAF 59/254 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- VCP | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 25/420 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- VPS13D | c.11135C>A p.T3712K | Missense Mutation (SNP) | VAF 77/160 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- VSTM2A | c.692T>A p.V231E | Missense Mutation (SNP) | VAF 100/386 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- WASL | c.652G>T p.D218Y | Missense Mutation (SNP) | VAF 124/405 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- WDFY4 | c.3296T>A p.L1099Q | Missense Mutation (SNP) | VAF 146/354 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- WDFY4 | c.3970C>A p.R1324S | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDR17 | c.412G>T p.A138S | Missense Mutation (SNP) | VAF 12/356 reads (3%) | SIFT tolerated (0.76); PolyPhen benign (0.001); called by muse, mutect2
- WSCD1 | c.1577del p.G526Afs*20 | Frame Shift Del (DEL) | VAF 74/222 reads (33%) | called by mutect2, pindel, varscan2
- XRN2 | c.2324G>A p.R775K | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBTB32 | c.700C>G p.P234A | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZFP62 | c.430G>T p.D144Y (on ENST00000502412 / NM_001377944.1; = p.D111Y on NM_152283.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- ZNF418 | c.1265G>A p.G422E | Missense Mutation (SNP) | VAF 60/101 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF726 | c.2089C>T p.H697Y | Missense Mutation (SNP) | VAF 122/338 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- AATK | c.1626C>A p.G542= (on ENST00000326724 / NM_001080395.3; = p.G439= on NM_004920.2) | Silent (SNP) | VAF 26/96 reads (27%) | called by muse, mutect2, varscan2
- ADAMTS2 | c.2901C>T p.R967= | Silent (SNP) | VAF 21/155 reads (14%) | called by muse, mutect2, varscan2
- ANAPC2 | c.1584G>T p.L528= | Silent (SNP) | VAF 47/224 reads (21%) | called by muse, mutect2, varscan2
- ANKRD42 | c.402T>C p.P134= | Silent (SNP) | VAF 94/278 reads (34%) | catalogued as rs1475667868; called by muse, varscan2
- ARHGAP17 | c.1284T>C p.V428= | Silent (SNP) | VAF 19/222 reads (9%) | catalogued as rs1402941781; called by muse, mutect2
- ATP13A5 | c.2088C>A p.R696= | Silent (SNP) | VAF 85/345 reads (25%) | called by muse, mutect2, varscan2
- C10orf71 | c.1992G>A p.K664= | Silent (SNP) | VAF 31/93 reads (33%) | called by muse, mutect2, varscan2
- C2CD4A | c.675G>T p.R225= | Silent (SNP) | VAF 11/69 reads (16%) | called by muse, mutect2, varscan2
- CACNA1H | c.5928T>C p.C1976= | Silent (SNP) | VAF 31/112 reads (28%) | called by muse, mutect2, varscan2
- CARS1 | c.1458A>G p.E486= | Silent (SNP) | VAF 23/146 reads (16%) | called by muse, mutect2, varscan2
- CBLN1 | c.549G>T p.S183= | Silent (SNP) | VAF 115/258 reads (45%) | catalogued as rs535574008, COSV99535796; called by muse, mutect2, varscan2
- CCDC74B | c.777A>C p.P259= | Silent (SNP) | VAF 22/97 reads (23%) | called by muse, mutect2, varscan2
- CDH8 | c.1674G>A p.L558= | Silent (SNP) | VAF 51/182 reads (28%) | catalogued as COSV100184044; called by muse, varscan2
- CDK20 | c.264G>A p.L88= | Silent (SNP) | VAF 14/168 reads (8%) | catalogued as rs1462943760; called by muse, mutect2
- CLIC5 | c.846T>C p.S282= (on ENST00000185206 / NM_001370649.1; = p.S123= on NM_016929.5) | Silent (SNP) | VAF 195/307 reads (64%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.621A>G p.T207= | Silent (SNP) | VAF 141/535 reads (26%) | called by muse, mutect2, varscan2
- COCH | c.1830C>T p.F610= (on ENST00000216361 / NM_001347720.1; = p.F545= on NM_004086.3) | Silent (SNP) | VAF 24/42 reads (57%) | catalogued as COSV53549881, COSV99363520; called by muse, mutect2, varscan2
- CRACDL | c.2316G>T p.T772= | Silent (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- CSMD3 | c.1056C>T p.T352= | Silent (SNP) | VAF 113/407 reads (28%) | catalogued as COSV99834823; called by muse, mutect2, varscan2
- CTNNA3 | c.960G>T p.T320= | Silent (SNP) | VAF 84/393 reads (21%) | catalogued as COSV65609538; called by muse, mutect2, varscan2
- CYFIP2 | c.3318C>A p.T1106= (on ENST00000616178 / NM_001291722.2; = p.T1081= on NM_014376.4) | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV59033047; called by muse, varscan2
- CYP21A2 | c.357C>T p.A119= | Silent (SNP) | VAF 159/501 reads (32%) | called by muse, mutect2, varscan2
- DAPK1 | c.3789G>T p.L1263= | Silent (SNP) | VAF 28/81 reads (35%) | called by muse, mutect2, varscan2
- DARS2 | c.852G>A p.E284= | Silent (SNP) | VAF 13/304 reads (4%) | called by muse, mutect2
- DLG5 | c.3990C>G p.V1330= | Silent (SNP) | VAF 12/175 reads (7%) | called by muse, mutect2
- DNAH14 | c.8127C>A p.P2709= (on ENST00000445597; = p.P3512= on NM_001367479.1) | Silent (SNP) | VAF 258/344 reads (75%) | called by muse, mutect2, varscan2
- DNAH5 | c.4383G>A p.K1461= | Silent (SNP) | VAF 22/322 reads (7%) | catalogued as COSV99453029; called by muse, mutect2
- DTHD1 | c.360A>G p.T120= (on ENST00000456874; = p.T245= on NM_001170700.3) | Silent (SNP) | VAF 64/181 reads (35%) | called by muse, varscan2
- EBLN1 | c.450G>A p.S150= | Silent (SNP) | VAF 66/333 reads (20%) | catalogued as rs755656089; called by muse, mutect2, varscan2
- ESRRG | c.802C>T p.L268= | Silent (SNP) | VAF 202/244 reads (83%) | catalogued as COSV100753897; called by muse, mutect2, varscan2
- F7 | c.435G>A p.K145= | Silent (SNP) | VAF 213/282 reads (76%) | called by muse, mutect2, varscan2
- FBXW4 | c.1668T>G p.S556= | Silent (SNP) | VAF 37/98 reads (38%) | catalogued as COSV58707814; called by muse, mutect2, varscan2
- FLAD1 | c.1494C>A p.L498= | Silent (SNP) | VAF 7/146 reads (5%) | called by muse, mutect2
- FOXE1 | c.768T>A p.A256= | Silent (SNP) | VAF 17/55 reads (31%) | called by muse, mutect2, varscan2
- FSD1 | c.168C>A p.S56= | Silent (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
- GDF2 | c.1164G>T p.V388= | Silent (SNP) | VAF 17/35 reads (49%) | called by muse, mutect2, varscan2
- GPR150 | c.450G>C p.A150= | Silent (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- GRIA1 | c.279T>A p.T93= | Silent (SNP) | VAF 39/242 reads (16%) | called by muse, mutect2, varscan2
- GSTM3 | c.18T>A p.S6= | Silent (SNP) | VAF 111/250 reads (44%) | called by muse, mutect2, varscan2
- KDM8 | c.1029G>A p.P343= | Silent (SNP) | VAF 18/115 reads (16%) | catalogued as rs753613325, COSV53729423; called by muse, mutect2, varscan2
- KIF3B | c.1914A>G p.P638= | Silent (SNP) | VAF 34/140 reads (24%) | called by muse, mutect2, varscan2
- KMT2D | c.14046A>T p.T4682= | Silent (SNP) | VAF 47/90 reads (52%) | called by muse, mutect2, varscan2
- LHX8 | c.93G>T p.G31= | Silent (SNP) | VAF 63/104 reads (61%) | called by muse, mutect2, varscan2
- LVRN | c.1761C>G p.V587= | Silent (SNP) | VAF 150/358 reads (42%) | called by muse, mutect2, varscan2
- LYPD6 | c.33G>T p.L11= | Silent (SNP) | VAF 48/231 reads (21%) | called by muse, mutect2, varscan2
- MAGEC3 | c.444A>G p.R148= | Silent (SNP) | VAF 37/58 reads (64%) | called by muse, mutect2, varscan2
- MAST3 | c.3249C>T p.T1083= | Silent (SNP) | VAF 30/283 reads (11%) | called by muse, mutect2, varscan2
- MC2R | c.702C>A p.P234= | Silent (SNP) | VAF 97/201 reads (48%) | catalogued as CD094229; called by muse, mutect2, varscan2
- MOV10 | c.72G>T p.R24= | Silent (SNP) | VAF 87/179 reads (49%) | called by muse, mutect2, varscan2
- MPHOSPH10 | c.1023T>A p.T341= | Silent (SNP) | VAF 52/144 reads (36%) | called by muse, varscan2
- MPP2 | c.495G>A p.V165= (on ENST00000461854 / NM_001278372.2; = p.V141= on NM_005374.5) | Silent (SNP) | VAF 126/340 reads (37%) | called by muse, mutect2, varscan2
- NAV3 | c.6738C>T p.C2246= (on ENST00000397909 / NM_001024383.2; = p.C2224= on NM_014903.6) | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as rs759341580; called by muse, mutect2, varscan2
- NCAPH2 | c.1341C>T p.P447= | Silent (SNP) | VAF 39/197 reads (20%) | catalogued as rs376176140; called by muse, mutect2, varscan2
- NEK1 | c.3537C>T p.C1179= | Silent (SNP) | VAF 45/159 reads (28%) | catalogued as rs772515579, COSV71457710; called by muse, mutect2, varscan2
- NEUROD1 | c.681C>G p.P227= | Silent (SNP) | VAF 36/94 reads (38%) | catalogued as COSV54549711; called by muse, mutect2, varscan2
- NPY5R | c.141C>A p.L47= | Silent (SNP) | VAF 19/68 reads (28%) | called by muse, mutect2, varscan2
- NRCAM | c.1845G>T p.T615= (on ENST00000379028 / NM_001371124.1; = p.T609= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 138/341 reads (40%) | called by muse, mutect2, varscan2
- OR2AG2 | c.340C>T p.L114= | Silent (SNP) | VAF 48/232 reads (21%) | catalogued as rs779937882; called by muse, mutect2, varscan2
- OR4X2 | c.117C>T p.L39= | Silent (SNP) | VAF 54/171 reads (32%) | called by muse, mutect2, varscan2
- OR5B21 | c.543A>G p.P181= | Silent (SNP) | VAF 79/229 reads (34%) | catalogued as rs201015117; called by muse, mutect2, varscan2
- OR6C68 | c.429T>C p.V143= | Silent (SNP) | VAF 10/234 reads (4%) | called by muse, mutect2
- PDZRN4 | c.1314T>C p.N438= (on ENST00000402685 / NM_001164595.2; = p.N180= on NM_013377.4) | Silent (SNP) | VAF 129/336 reads (38%) | catalogued as rs1473078932; called by muse, mutect2, varscan2
- PHRF1 | c.411A>G p.E137= | Silent (SNP) | VAF 27/122 reads (22%) | called by muse, mutect2, varscan2
- PTPRG | c.3057C>A p.I1019= | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as COSV99876559; called by muse, mutect2, varscan2
- RGS7BP | c.369G>A p.R123= | Silent (SNP) | VAF 43/140 reads (31%) | called by muse, mutect2, varscan2
- SEC14L5 | c.324G>T p.V108= | Silent (SNP) | VAF 18/79 reads (23%) | called by muse, mutect2, varscan2
- SLC22A16 | c.1215G>A p.V405= | Silent (SNP) | VAF 30/174 reads (17%) | called by muse, mutect2
- SLC9A2 | c.1146C>T p.T382= | Silent (SNP) | VAF 97/229 reads (42%) | catalogued as rs894966235; called by muse, mutect2, varscan2
- SMAD4 | c.1452G>T p.L484= | Silent (SNP) | VAF 169/324 reads (52%) | called by muse, mutect2, varscan2
- SRGAP3 | c.1488C>T p.L496= | Silent (SNP) | VAF 88/166 reads (53%) | called by muse, mutect2, varscan2
- TENT5B | c.871C>A p.R291= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as COSV56693159; called by muse, mutect2, varscan2
- TEPSIN | c.444G>A p.P148= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs141474303; called by mutect2, varscan2
- TERF2IP | c.954C>G p.S318= | Silent (SNP) | VAF 54/115 reads (47%) | called by muse, mutect2, varscan2
- TMC5 | c.397C>A p.R133= | Silent (SNP) | VAF 41/194 reads (21%) | catalogued as rs376637338; called by muse, mutect2, varscan2
- TRAV22 | c.291C>A p.S97= | Silent (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
- TRAV8-1 | c.318T>A p.A106= | Silent (SNP) | VAF 6/10 reads (60%) | called by muse, mutect2, varscan2
- TRBV29-1 | c.132C>A p.V44= | Silent (SNP) | VAF 157/444 reads (35%) | called by muse, mutect2, varscan2
- TRIM58 | c.217C>A p.R73= | Silent (SNP) | VAF 18/26 reads (69%) | catalogued as rs781535169; called by muse, mutect2, varscan2
- TSPEAR | c.1926C>T p.A642= | Silent (SNP) | VAF 54/130 reads (42%) | called by muse, mutect2, varscan2
- TTC23 | c.471A>G p.A157= | Silent (SNP) | VAF 26/129 reads (20%) | called by muse, varscan2
- TTN | c.13893T>A p.P4631= (on ENST00000591111; = p.P3704= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2
- TUBA3C | c.642G>A p.R214= | Silent (SNP) | VAF 93/129 reads (72%) | called by muse, mutect2, varscan2
- UNC5A | c.2439C>A p.P813= | Silent (SNP) | VAF 55/176 reads (31%) | called by muse, mutect2, varscan2
- USH2A | c.9609A>T p.G3203= | Silent (SNP) | VAF 503/643 reads (78%) | catalogued as rs530878261; called by muse, mutect2, varscan2
- WT1 | c.675C>A p.V225= | Silent (SNP) | VAF 70/322 reads (22%) | called by muse, mutect2, varscan2
- XKR7 | c.1401C>T p.D467= | Silent (SNP) | VAF 38/133 reads (29%) | catalogued as rs1310101503, COSV73812896; called by muse, mutect2, varscan2
- ZBTB20 | c.192A>T p.S64= | Silent (SNP) | VAF 47/103 reads (46%) | called by muse, mutect2, varscan2
- ZNF479 | c.159C>T p.V53= | Silent (SNP) | VAF 45/192 reads (23%) | called by muse, varscan2
- AC006305.1 | n.910G>T | RNA (SNP) | VAF 63/96 reads (66%) | called by muse, mutect2, varscan2
- AC103993.1 | n.107C>T | RNA (SNP) | VAF 58/213 reads (27%) | catalogued as rs914326829; called by muse, mutect2, varscan2
- AC136628.2 | n.838C>A | RNA (SNP) | VAF 36/125 reads (29%) | catalogued as rs1046474854; called by muse, mutect2, varscan2
- AC244517.10 | c.36-9345G>T | Intron (SNP) | VAF 43/182 reads (24%) | called by muse, mutect2, varscan2
- ADGB | c.752+23A>C | Intron (SNP) | VAF 15/133 reads (11%) | called by muse, varscan2
- AFDN | chr6:167825897 G>A | 5'Flank (SNP) | VAF 8/16 reads (50%) | catalogued as rs112059996; called by muse, mutect2
- AGAP7P | n.464G>A | RNA (SNP) | VAF 56/286 reads (20%) | called by muse, mutect2, varscan2
- AGAP7P | n.1543C>A | RNA (SNP) | VAF 41/317 reads (13%) | called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840500 G>T | 5'Flank (SNP) | VAF 79/279 reads (28%) | catalogued as COSV58348880; called by muse, mutect2, varscan2
- ANKRD20A8P | n.859A>G | RNA (SNP) | VAF 85/577 reads (15%) | catalogued as rs782780769; called by muse, mutect2, varscan2
- ANKRD26P1 | n.1673C>A | RNA (SNP) | VAF 48/123 reads (39%) | catalogued as rs1380579895; called by muse, mutect2, varscan2
- AP003062.1 | n.351C>A | RNA (SNP) | VAF 171/792 reads (22%) | called by muse, varscan2
- APLF | c.*72A>T | 3'UTR (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130915873 G>A | 5'Flank (SNP) | VAF 11/56 reads (20%) | called by muse, varscan2
- BLK | c.*181C>A | 3'UTR (SNP) | VAF 12/21 reads (57%) | called by muse, mutect2, varscan2
- C12orf50 | c.-95G>C | 5'UTR (SNP) | VAF 116/179 reads (65%) | catalogued as COSV100072057; called by muse, mutect2, varscan2
- CCDC140 | n.735C>A | RNA (SNP) | VAF 40/153 reads (26%) | catalogued as COSV54676519; called by muse, mutect2, varscan2
- CCNYL2 | n.836-1800C>A | Intron (SNP) | VAF 7/65 reads (11%) | called by muse, mutect2, varscan2
- CHRNA4 | c.*3328G>T | 3'UTR (SNP) | VAF 141/411 reads (34%) | catalogued as rs1271024345; called by muse, mutect2, varscan2
- CIP2A | c.103-494A>T | Intron (SNP) | VAF 209/414 reads (50%) | called by muse, mutect2, varscan2
- CLUHP11 | n.273C>G | RNA (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- COMMD2 | c.228+20G>C | Intron (SNP) | VAF 48/290 reads (17%) | called by muse, mutect2, varscan2
- COX7B2 | c.*33A>G | 3'UTR (SNP) | VAF 66/201 reads (33%) | catalogued as rs754501633, COSV100259914; called by muse, mutect2, varscan2
- CSMD3 | c.178+59943G>T | Intron (SNP) | VAF 239/711 reads (34%) | called by muse, mutect2, varscan2
- CYP2R1 | c.-2C>G | 5'UTR (SNP) | VAF 26/206 reads (13%) | catalogued as rs200462787, COSV58127056; called by muse, mutect2, varscan2
- EFCAB2 | c.781+36G>T | Intron (SNP) | VAF 49/64 reads (77%) | called by muse, mutect2, varscan2
- FCRL4 | c.1360+66C>T | Intron (SNP) | VAF 46/184 reads (25%) | called by muse, mutect2, varscan2
- GABRA2 | c.1060-5645G>T | Intron (SNP) | VAF 60/166 reads (36%) | catalogued as rs1291249716; called by muse, varscan2
- GIPC1 | c.656-29C>T | Intron (SNP) | VAF 7/13 reads (54%) | catalogued as rs1441359328; called by muse, mutect2
- GRIN1 | c.671+34A>T | Intron (SNP) | VAF 121/371 reads (33%) | called by muse, mutect2, varscan2
- HERC2P3 | n.147G>T | RNA (SNP) | VAF 85/418 reads (20%) | called by muse, mutect2, varscan2
- IGKV1-16 | c.-11C>A | 5'UTR (SNP) | VAF 63/192 reads (33%) | called by muse, mutect2, varscan2
- IGSF11 | c.-7C>T | 5'UTR (SNP) | VAF 28/89 reads (31%) | called by muse, mutect2, varscan2
- IQCE | c.1632+54G>T | Intron (SNP) | VAF 54/170 reads (32%) | called by muse, mutect2, varscan2
- JPH3 | chr16:87702170 C>T | 3'Flank (SNP) | VAF 114/520 reads (22%) | catalogued as rs549199294; called by muse, mutect2, varscan2
- KRT18P23 | chr22:44571490 C>T | 3'Flank (SNP) | VAF 46/103 reads (45%) | called by muse, mutect2, varscan2
- LY6H | c.-14G>T | 5'UTR (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- MAP1B | c.-1G>T | 5'UTR (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- MGAM | c.4619-8768T>C | Intron (SNP) | VAF 84/274 reads (31%) | catalogued as rs1484679888; called by muse, mutect2, varscan2
- MIF4GD | c.82+662A>G | Intron (SNP) | VAF 22/100 reads (22%) | called by muse, varscan2
- MIR9-1HG | n.19A>G | RNA (SNP) | VAF 136/302 reads (45%) | called by muse, varscan2
- MMP2 | c.*33C>T | 3'UTR (SNP) | VAF 35/150 reads (23%) | called by muse, mutect2, varscan2
- MPC1 | c.76-90G>T | Intron (SNP) | VAF 51/171 reads (30%) | called by muse, varscan2
- NHSL2 | chrX:72143492 T>C | 3'Flank (SNP) | VAF 67/93 reads (72%) | called by muse, mutect2, varscan2
- NOVA1 | c.519+47G>T | Intron (SNP) | VAF 47/328 reads (14%) | called by muse, mutect2, varscan2
- NPR3 | chr5:32710710 G>T | 5'Flank (SNP) | VAF 77/187 reads (41%) | called by muse, mutect2, varscan2
- NRBP2 | c.1438-40G>T | Intron (SNP) | VAF 35/82 reads (43%) | called by muse, mutect2, varscan2
- NRP1 | c.1924+9T>A | Intron (SNP) | VAF 50/106 reads (47%) | called by muse, varscan2
- OR7E5P | n.358G>T | RNA (SNP) | VAF 89/243 reads (37%) | called by muse, mutect2, varscan2
- OR8H1 | c.*67G>C | 3'UTR (SNP) | VAF 14/64 reads (22%) | called by muse, varscan2
- OR8H1 | c.*64C>A | 3'UTR (SNP) | VAF 24/64 reads (38%) | called by muse, varscan2
- OSGIN1 | chr16:83948893 G>A | 5'Flank (SNP) | VAF 17/116 reads (15%) | catalogued as rs1468377508; called by muse, mutect2, varscan2
- PEX11B | chr1:145919704 A>T | 5'Flank (SNP) | VAF 63/157 reads (40%) | called by muse, mutect2, varscan2
- PIPSL | n.198T>C | RNA (SNP) | VAF 138/321 reads (43%) | called by muse, mutect2, varscan2
- PLCH2 | c.2959+378G>A | Intron (SNP) | VAF 32/57 reads (56%) | catalogued as rs1264367895; called by muse, mutect2, varscan2
- PTPRQ | chr12:80435049 G>T | 5'Flank (SNP) | VAF 114/199 reads (57%) | called by muse, varscan2
- RBP3 | c.-2C>A | 5'UTR (SNP) | VAF 52/142 reads (37%) | called by muse, varscan2
- RGS10 | c.49+6092G>T | Intron (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
- RGS4 | chr1:163069252 G>T | 5'Flank (SNP) | VAF 50/120 reads (42%) | catalogued as rs1269865779; called by muse, mutect2, varscan2
- RGS4 | chr1:163069253 G>T | 5'Flank (SNP) | VAF 51/122 reads (42%) | called by muse, mutect2, varscan2
- RN7SL484P | chr15:99791868 C>A | 3'Flank (SNP) | VAF 114/270 reads (42%) | called by muse, mutect2, varscan2
- RPL18A | c.-28G>T | 5'UTR (SNP) | VAF 62/303 reads (20%) | called by muse, mutect2, varscan2
- SNORD116-19 | n.81G>C | RNA (SNP) | VAF 129/376 reads (34%) | called by muse, mutect2, varscan2
- SOX8 | chr16:981199 C>A | 5'Flank (SNP) | VAF 38/136 reads (28%) | called by muse, mutect2, varscan2
- SPATA31C2 | n.1441A>G | RNA (SNP) | VAF 137/486 reads (28%) | catalogued as rs1435891454; called by muse, mutect2, varscan2
- SPATA31C2 | n.1156C>A | RNA (SNP) | VAF 163/262 reads (62%) | called by muse, mutect2, varscan2
- SPATS1 | c.*34C>T | 3'UTR (SNP) | VAF 57/83 reads (69%) | catalogued as COSV55822079; called by muse, mutect2, varscan2
- TBC1D29P | n.2801G>T | RNA (SNP) | VAF 76/276 reads (28%) | catalogued as COSV70434141; called by muse, varscan2
- TMCO1 | c.*2135A>T | 3'UTR (SNP) | VAF 42/146 reads (29%) | catalogued as rs918407287; called by muse, mutect2, varscan2
- TRPM3 | chr9:70535403 G>T | 3'Flank (SNP) | VAF 115/314 reads (37%) | catalogued as rs1335454592; called by muse, mutect2, varscan2
- TSPAN3 | c.-16G>A | 5'UTR (SNP) | VAF 36/82 reads (44%) | catalogued as rs1401921694; called by muse, mutect2, varscan2
- TTN | c.-76A>T | 5'UTR (SNP) | VAF 15/88 reads (17%) | called by muse, mutect2, varscan2
- WASF4P | n.1348C>T | RNA (SNP) | VAF 74/110 reads (67%) | catalogued as rs782084288; called by muse, mutect2, varscan2
- WDR49 | c.-65-17133C>T | Intron (SNP) | VAF 14/198 reads (7%) | called by muse, mutect2
- WDR49 | c.-65-17134T>A | Intron (SNP) | VAF 12/195 reads (6%) | called by muse, mutect2
- WT1 | chr11:32439000 G>T | 5'Flank (SNP) | VAF 98/293 reads (33%) | called by muse, mutect2, varscan2
- ZEB2 | c.73+4382dup | Intron (INS) | VAF 56/180 reads (31%) | called by mutect2, pindel, varscan2
- ZNF165 | chr6:28091305 C>G | 3'Flank (SNP) | VAF 202/331 reads (61%) | called by muse, mutect2, varscan2
- ZNF720 | c.361+1610C>G | Intron (SNP) | VAF 15/78 reads (19%) | called by muse, mutect2, varscan2
- ZNF99 | c.*3134T>A | 3'UTR (SNP) | VAF 16/26 reads (62%) | called by muse, mutect2, varscan2
